Somatic mutation profile of tumor specimen TCGA-EE-A2MH-06A (aliquot TCGA-EE-A2MH-06A-11D-A197-08) from TCGA case TCGA-EE-A2MH, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 66.8 years (24,399 days).
Specimen TCGA-EE-A2MH-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d96d90e-f48f-427b-9420-6c6ddb4de627.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2MH-10A (Blood Derived Normal), aliquot TCGA-EE-A2MH-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0485414e-8c90-4f1e-a5f2-03f9751786f0

The open-access MAF lists 170 somatic variants for this specimen: 100 protein-altering or splice-affecting, 65 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 65, Nonsense Mutation 5, Intron 3, Splice Region 3, Splice Site 3, RNA 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, varscan2
- KAT8 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 19/81 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54896480; called by muse, mutect2, varscan2
- A2ML1 | c.907C>G p.L303V | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as COSV55294325; called by muse, mutect2, varscan2
- AC013477.1 | c.2467G>A p.E823K | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as COSV53654343, COSV99548749; called by muse, mutect2, varscan2
- AICDA | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as rs775814283, COSV57564503; called by muse, mutect2, varscan2
- ALG10B | c.1030C>T p.H344Y | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs952215654, COSV58143882; called by muse, varscan2
- ALPK1 | c.2008C>T p.P670S | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.573); catalogued as COSV51587947; called by muse, mutect2, varscan2
- APBB1 | c.1562C>T p.S521F | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as COSV100193972, COSV54978135; called by muse, mutect2, varscan2
- ASPM | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99660074; called by muse, mutect2, varscan2
- ASPM | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV99660076; called by muse, mutect2, varscan2
- ATP13A4 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 37/222 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.597); catalogued as COSV55071924; called by muse, mutect2, varscan2
- CCDC141 | c.2953G>A p.E985K | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.972); catalogued as COSV55369772; called by muse, mutect2
- CFAP74 | c.816G>A p.M272I | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV54569457, COSV54570183; called by muse, mutect2, varscan2
- COL12A1 | c.8860G>A p.G2954R | Missense Mutation (SNP) | VAF 78/291 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59400617; called by muse, mutect2, varscan2
- COL21A1 | c.1976G>A p.G659D | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55170707; called by muse, mutect2, varscan2
- COL28A1 | c.2984C>T p.S995L | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs762837552, COSV68083239; called by muse, mutect2, varscan2
- COL9A3 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV100673357; called by muse, mutect2, varscan2
- COL9A3 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as rs768298010, COSV100673358; called by muse, mutect2, varscan2
- CPEB1 | c.667C>T p.P223S (on ENST00000617958; = p.P163S on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.022); catalogued as COSV55620153; called by muse, mutect2, varscan2
- CROCC | c.4652C>T p.S1551L | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.082); catalogued as rs745806335, COSV100978067, COSV65013387; called by mutect2, varscan2
- DHRS3 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT tolerated (0.93); PolyPhen benign (0.074); catalogued as rs754683233, COSV66108501; called by muse, mutect2, varscan2
- DNAH1 | c.6995A>C p.K2332T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV70231944; called by muse, mutect2
- DNAH7 | c.10756C>T p.H3586Y | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1241893715, COSV56761425; called by muse, mutect2, varscan2
- DTNA | c.1823-2A>C p.X608_splice | Splice Site (SNP) | VAF 3/37 reads (8%) | catalogued as COSV52009188; called by muse, mutect2
- ECEL1 | c.1750C>T p.P584S | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as COSV58813271; called by muse, mutect2, varscan2
- EEF1A2 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 124/171 reads (73%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.214); catalogued as COSV99419267; called by muse, varscan2
- EGLN1 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV64149852; called by muse, mutect2, varscan2
- FOXA2 | c.1247C>T p.S416F (on ENST00000377115 / NM_153675.3; = p.S422F on NM_021784.5) | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1482599735, COSV65796646; called by muse, mutect2, varscan2
- FOXD1 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61076637; called by muse, mutect2, varscan2
- GAR1 | c.213C>T p.V71= | Splice Region (SNP) | VAF 38/156 reads (24%) | catalogued as rs201487663, COSV56993602; called by muse, mutect2, varscan2
- GPR173 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV60236930; called by muse, mutect2, varscan2
- GRIA1 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1284783625, COSV53612511; called by muse, mutect2, varscan2
- GRIN2B | c.2305G>A p.D769N | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV74206740; called by muse, mutect2, varscan2
- HCN4 | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56085187; called by muse, mutect2, varscan2
- HEMK1 | c.552C>T p.S184= | Splice Region (SNP) | VAF 14/83 reads (17%) | catalogued as COSV51751347; called by muse, mutect2, varscan2
- HIF3A | c.1885C>T p.P629S (on ENST00000377670 / NM_152795.4; = p.P560S on NM_022462.4) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs1314291825, COSV52201380; called by muse, mutect2, varscan2
- HSPG2 | c.5114C>T p.P1705L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65974011; called by muse, mutect2, varscan2
- HYAL4 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV56139356, COSV99772222; called by muse, mutect2, varscan2
- INPP5K | c.1294C>T p.P432S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.154); catalogued as COSV57441603; called by muse, mutect2
- KCNQ5 | c.2420G>A p.S807N | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.038); catalogued as COSV59670135; called by muse, varscan2
- KIF14 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV66262620; called by muse, mutect2, varscan2
- KIR3DX1 | n.956G>A | Splice Region (SNP) | VAF 18/85 reads (21%) | catalogued as COSV55598245, COSV99683694; called by muse, mutect2, varscan2
- KRTAP5-10 | c.274_275insA p.G92Efs*55 | Frame Shift Ins (INS) | VAF 35/116 reads (30%) | catalogued as rs759760385; called by muse*, mutect2, varscan2*
- LCE1B | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.351); catalogued as COSV63980450; called by muse, mutect2, varscan2
- MAPK14 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV100004823; called by muse, mutect2, varscan2
- MTDH | c.1603C>T p.Q535* | Nonsense Mutation (SNP) | VAF 228/302 reads (75%) | catalogued as COSV60345299; called by muse, mutect2, varscan2
- MTMR14 | c.1829C>T p.A610V (on ENST00000296003 / NM_001077525.3; = p.A498V on NM_022485.5) | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); catalogued as rs1295239715, COSV56006200; called by muse, mutect2, varscan2
- MUC16 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.014); catalogued as COSV67443354; called by muse, mutect2, varscan2
- MYO1A | c.2899G>A p.G967R | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1354540592, COSV55655660; called by muse, mutect2, varscan2
- MYRF | c.271C>T p.P91S (on ENST00000278836 / NM_001127392.3; = p.P82S on NM_013279.4) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.272); catalogued as COSV53891136; called by muse, mutect2
- NCAN | c.3359C>T p.S1120F | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as rs199989580, COSV53046796; called by muse, mutect2, varscan2
- NEB | c.6569A>G p.E2190G | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51434053; called by muse, mutect2, varscan2
- NLRP3 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs180177464, CM068199, COSV60227851; ClinVar: not provided; called by muse, mutect2, varscan2
- NR1H2 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 39/202 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99516270; called by muse, mutect2, varscan2
- NR1H2 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs200227817, COSV99516283; called by muse, mutect2, varscan2
- NR1H4 | c.259C>T p.P87S (on ENST00000551379 / NM_001206993.2; = p.P77S on NM_005123.4) | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV51854108; called by muse, mutect2, varscan2
- OTOGL | c.5030C>T p.S1677F (on ENST00000547103; = p.S1668F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/303 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.187); catalogued as rs755374459, COSV54017686; called by muse, mutect2, varscan2
- PADI1 | c.1411G>A p.G471S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1350404399, COSV100969059; called by muse, mutect2, varscan2
- PAPPA2 | c.3746G>A p.R1249K | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV62803574; called by muse, mutect2, varscan2
- PCDHB9 | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 45/222 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); catalogued as rs781934609, COSV53381274; called by muse, mutect2, varscan2
- PDE11A | c.1886G>A p.R629Q | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs777041963, COSV53691028, COSV53699752; called by muse, mutect2, varscan2
- PDE1C | c.1478C>T p.P493L | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1191596537, COSV58519866; called by muse, mutect2
- PENK | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as rs149967411; called by muse, mutect2, varscan2
- PGR | c.2218C>T p.R740* | Nonsense Mutation (SNP) | VAF 11/90 reads (12%) | catalogued as rs1315135533, COSV54796997; called by muse, mutect2, varscan2
- PI4K2B | c.787T>G p.Y263D | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53512133; called by muse, mutect2
- PKHD1L1 | c.6806G>A p.R2269Q | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs762177904, COSV65747256; called by muse, mutect2, varscan2
- PNPLA4 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66854271; called by muse, mutect2, varscan2
- PNPLA7 | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.059); catalogued as COSV53002035; called by muse, mutect2
- POLR1A | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV55695683; called by muse, mutect2, varscan2
- PRLR | c.193C>T p.H65Y | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV51497657; called by muse, mutect2, varscan2
- PROX1 | c.307A>T p.K103* | Nonsense Mutation (SNP) | VAF 25/105 reads (24%) | catalogued as COSV54781066; called by muse, mutect2, varscan2
- PSD4 | c.2354G>A p.R785Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs139776921, COSV55526043; called by muse, mutect2
- PTPRD | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777779009, COSV61928995; called by muse, mutect2, varscan2
- PXDNL | c.330C>G p.I110M | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62492851; called by muse, mutect2, varscan2
- RELN | c.4036G>A p.G1346R | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.729); catalogued as COSV59016769, COSV59024126; called by muse, mutect2, varscan2
- RFPL2 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs936769250, COSV50709200; called by muse, mutect2, varscan2
- RIMKLA | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV68909848; called by muse, mutect2, varscan2
- RUNX2 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs104893995, CM020508, CM992608, COSV61840595; called by muse, mutect2, varscan2
- RYR2 | c.12620C>T p.S4207L | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV63666745; called by muse, mutect2, varscan2
- SCLT1 | c.877G>T p.V293L | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV55409130; called by muse, mutect2, varscan2
- SCN2A | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 42/264 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV51847733; called by muse, mutect2, varscan2
- SERPINB2 | c.117G>A p.M39I | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV55093477; called by muse, mutect2
- SLC4A10 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs1261502891, COSV55788035; called by muse, mutect2
- SMC5 | c.1388C>T p.T463M | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63194084; called by muse, mutect2, varscan2
- SUCNR1 | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 17/95 reads (18%) | catalogued as rs748612865, COSV62912530; called by muse, mutect2, varscan2
- SUSD2 | c.1931C>T p.S644F | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64204614; called by muse, mutect2, varscan2
- TGS1 | c.1906C>T p.P636S | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.579); catalogued as COSV52699778; called by muse, mutect2, varscan2
- TH | c.592C>T p.P198S (on ENST00000381178 / NM_199292.3; = p.P167S on NM_000360.4) | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60767838; called by muse, varscan2
- TKTL2 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1465572480, COSV54919993; called by muse, mutect2
- TLL1 | c.2669G>A p.R890Q | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.617); catalogued as rs1003510527, COSV50263347, COSV50274981; called by muse, mutect2, varscan2
- TRIOBP | c.2381C>T p.S794F | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.017); catalogued as COSV60373483; called by muse, mutect2, varscan2
- TULP3 | c.49C>T p.H17Y | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV68118278; called by muse, mutect2, varscan2
- USP29 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV54237626; called by muse, mutect2, varscan2
- VPS13B | c.9853C>T p.P3285S | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.769); catalogued as COSV62134981; called by muse, mutect2, varscan2
- ZNF385D | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55763057; called by muse, mutect2, varscan2
- ACACA | c.4597G>A p.V1533I | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- ACACA | c.4596G>A p.M1532I | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- CPEB2 | c.2853+2dup p.X951_splice | Splice Site (INS) | VAF 22/145 reads (15%) | called by mutect2, pindel, varscan2
- GPR179 | c.794+1G>A p.X265_splice | Splice Site (SNP) | VAF 34/162 reads (21%) | called by muse, mutect2, varscan2
- OR1L1 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 3/20 reads (15%) | PolyPhen benign (0); called by muse, mutect2
- A1CF | c.429C>T p.I143= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV50983036; called by muse, varscan2
- ADAR | c.3120C>T p.I1040= | Silent (SNP) | VAF 22/99 reads (22%) | catalogued as rs771995348, COSV52712679; called by muse, mutect2, varscan2
- ADGRA2 | c.1884C>T p.S628= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as COSV59445233; called by muse, mutect2
- ADGRG4 | c.7587C>T p.A2529= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV54961318; called by muse, mutect2, varscan2
- ADGRL2 | c.432G>A p.V144= | Silent (SNP) | VAF 31/152 reads (20%) | catalogued as COSV54652406; called by muse, mutect2, varscan2
- ANK3 | c.8793G>A p.R2931= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV55068009; called by muse, mutect2, varscan2
- AOC3 | c.1245C>T p.F415= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV53827764; called by muse, mutect2
- BPIFA3 | c.663G>A p.V221= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as rs139539413, COSV64926027; called by muse, mutect2, varscan2
- CCDC141 | c.2952G>A p.L984= | Silent (SNP) | VAF 9/97 reads (9%) | catalogued as COSV99836571; called by muse, mutect2
- CNTNAP1 | c.1561C>T p.L521= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as COSV52852193; called by muse, mutect2, varscan2
- CRB1 | c.2019G>A p.K673= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as rs762613347, COSV66331616; ClinVar: likely benign; called by muse, mutect2, varscan2
- DHPS | c.231G>A p.L77= | Silent (SNP) | VAF 24/146 reads (16%) | catalogued as COSV52952568; called by muse, mutect2, varscan2
- DLK2 | c.813G>A p.V271= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as COSV99767046; called by muse, varscan2
- DNAH5 | c.4569T>G p.P1523= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV54237883; called by muse, mutect2, varscan2
- DRC7 | c.1356C>T p.Y452= | Silent (SNP) | VAF 27/119 reads (23%) | catalogued as COSV61056360; called by muse, mutect2, varscan2
- EEF1A2 | c.1197G>A p.A399= | Silent (SNP) | VAF 129/176 reads (73%) | catalogued as COSV99419269; called by muse, varscan2
- ELK1 | c.243C>T p.F81= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as rs763088656, COSV55953832; called by muse, mutect2, varscan2
- ERVW-1 | c.948A>G p.K316= | Silent (SNP) | VAF 29/180 reads (16%) | catalogued as COSV71259494; called by muse, mutect2, varscan2
- ESPN | c.381C>T p.G127= | Silent (SNP) | VAF 26/115 reads (23%) | catalogued as rs552379031, COSV64704957; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT4 | c.7467G>A p.A2489= | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as rs746567486, COSV58695874; called by muse, mutect2, varscan2
- GFPT2 | c.1977C>T p.F659= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV53810332; called by muse, mutect2
- GPRIN3 | c.1458G>A p.G486= | Silent (SNP) | VAF 22/132 reads (17%) | catalogued as rs1405956399, COSV60885515; called by muse, varscan2
- HNF1B | c.24C>T p.L8= | Silent (SNP) | VAF 65/291 reads (22%) | called by muse, mutect2, varscan2
- INSC | c.1458C>T p.V486= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV65411665; called by muse, mutect2
- INTS3 | c.1314C>T p.C438= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV59679513; called by muse, mutect2, varscan2
- IRAG1 | c.711G>A p.G237= | Silent (SNP) | VAF 22/119 reads (18%) | catalogued as rs1230325020, COSV70212019; called by muse, mutect2
- ITGA5 | c.1950C>T p.I650= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as rs370202706, COSV53219263; called by muse, mutect2, varscan2
- ITPRIP | c.1173C>T p.F391= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV53391487, COSV53392273; called by muse, mutect2, varscan2
- JUND | c.390C>A p.A130= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV53254766; called by muse, mutect2, varscan2
- KCNB2 | c.942C>T p.L314= | Silent (SNP) | VAF 86/122 reads (70%) | catalogued as rs145537672, COSV73049623; called by muse, mutect2, varscan2
- KIAA0232 | c.1842C>T p.L614= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV56927077; called by muse, varscan2
- KIT | c.144C>T p.V48= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV55410143; called by muse, mutect2, varscan2
- KRTAP4-4 | c.111C>T p.R37= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as rs759413104, COSV66811414; called by muse, mutect2, varscan2
- LILRA5 | c.288G>A p.K96= | Silent (SNP) | VAF 46/244 reads (19%) | catalogued as COSV56643948; called by muse, mutect2, varscan2
- MED25 | c.924T>A p.P308= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV57205873; called by mutect2, varscan2
- MUC16 | c.12840C>T p.I4280= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV67478391; called by muse, mutect2, varscan2
- NAA80 | c.738C>T p.P246= (on ENST00000417393 / NM_001200018.2; = p.P268= on NM_012191.4) | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV99807574; called by muse, mutect2, varscan2
- NAA80 | c.279C>T p.S93= (on ENST00000417393 / NM_001200018.2; = p.S115= on NM_012191.4) | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV99807576; called by muse, mutect2, varscan2
- NNT | c.1800C>T p.L600= | Silent (SNP) | VAF 34/169 reads (20%) | catalogued as COSV52927003; called by muse, mutect2, varscan2
- NUP93 | c.693A>C p.T231= | Silent (SNP) | VAF 25/134 reads (19%) | catalogued as COSV57432062; called by muse, mutect2, varscan2
- PFKM | c.1944G>A p.G648= | Silent (SNP) | VAF 36/158 reads (23%) | catalogued as COSV56658900; called by muse, mutect2, varscan2
- PHACTR3 | c.318G>A p.E106= | Silent (SNP) | VAF 150/386 reads (39%) | catalogued as COSV63030894; called by muse, mutect2, varscan2
- PIH1D1 | c.816C>T p.F272= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV51807832; called by muse, mutect2, varscan2
- RBM6 | c.531C>T p.G177= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as rs1458775263, COSV56485136; called by muse, mutect2, varscan2
- SCAMP3 | c.300G>A p.L100= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV56946347; called by muse, mutect2, varscan2
- SCN11A | c.3189C>T p.I1063= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs745865328, COSV56573613; called by muse, mutect2, varscan2
- SLC25A37 | c.858C>T p.F286= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV51564940; called by muse, mutect2
- SLC36A1 | c.48C>T p.S16= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV54655049; called by muse, mutect2
- SLC38A1 | c.438G>A p.G146= | Silent (SNP) | VAF 24/128 reads (19%) | catalogued as COSV67063292; called by muse, mutect2, varscan2
- SLIT1 | c.606C>T p.N202= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV56593279; called by muse, mutect2, varscan2
- SNCAIP | c.1428G>A p.L476= | Silent (SNP) | VAF 23/114 reads (20%) | catalogued as COSV54415318; called by muse, mutect2, varscan2
- SOCS3 | c.417A>T p.P139= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV58270907; called by muse, mutect2, varscan2
- SPINK5 | c.321G>A p.G107= | Silent (SNP) | VAF 17/114 reads (15%) | catalogued as COSV56258167; called by muse, mutect2, varscan2
- TAS2R41 | c.429C>T p.I143= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as COSV68765580; called by muse, mutect2, varscan2
- TBX22 | c.708C>T p.S236= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV64786916; called by muse, mutect2, varscan2
- TM4SF20 | c.585A>G p.L195= | Silent (SNP) | VAF 7/101 reads (7%) | catalogued as COSV58819057; called by muse, mutect2
- TM4SF5 | c.570G>A p.R190= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as rs866653895, COSV54497303; called by muse, mutect2, varscan2
- TMIE | c.252G>A p.R84= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV58406087; called by muse, varscan2
- TRIM44 | c.621C>T p.H207= | Silent (SNP) | VAF 19/152 reads (13%) | catalogued as COSV54985782; called by muse, mutect2, varscan2
- TRPC4 | c.924G>A p.Q308= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV59007255; called by muse, mutect2
- TSHZ2 | c.2826C>T p.I942= | Silent (SNP) | VAF 15/166 reads (9%) | catalogued as COSV61589896; called by muse, mutect2
- USP6 | c.1365C>T p.P455= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as rs547027041, COSV51488357; called by muse, mutect2
- VCPIP1 | c.732G>A p.Q244= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV60048979; called by muse, mutect2, varscan2
- WDR61 | c.606C>T p.S202= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs763912660, COSV51217210; called by muse, mutect2, varscan2
- ZNF217 | c.2166A>G p.P722= | Silent (SNP) | VAF 18/224 reads (8%) | catalogued as COSV56599538; called by muse, mutect2
- CARMIL3 | chr14:24048773 C>T | 5'Flank (SNP) | VAF 35/123 reads (28%) | catalogued as rs565233486; called by muse, mutect2, varscan2
- HMGA2 | c.250-36268C>T | Intron (SNP) | VAF 49/227 reads (22%) | catalogued as COSV100666531; called by muse, mutect2, varscan2
- OR2U1P | n.809C>T | RNA (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2, varscan2
- RIMS2 | c.1692+305G>A | Intron (SNP) | VAF 21/45 reads (47%) | catalogued as rs377485905; called by muse, mutect2, varscan2
- RMDN2 | c.452+21919G>A | Intron (SNP) | VAF 16/72 reads (22%) | catalogued as COSV52227133; called by muse, mutect2, varscan2
